Gene-level copy-number profile of tumor specimen TCGA-C5-A902-01A from TCGA case TCGA-C5-A902, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 35.5 years (12,959 days).
Specimen TCGA-C5-A902-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.3387f740-d44d-4fdc-81c5-e2cec69f607c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A902-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/42cb05e7-ec58-4d5a-99fb-c2bee437c651

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 10,845; copy number 2: 41,455; copy number 3: 6,354; copy number 4: 168; copy number 5: 844; copy number 6: 59; copy number 10: 46; copy number 18: 5; copy number 19: 26; copy number 34: 8.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:115,828,200–115,958,599, 3 genes: ATG12, AP3S1, LINCADL.
- chr5:115,974,513–115,976,275, 1 gene: DDX43P1.
- chr20:14,322,985–14,758,056, 6 genes: FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 988 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–161,699,607, 844 genes, copy number 5 (broad region; genes not listed).
- chr7:50,839,363–51,729,716, 12 genes, copy number 10 (within-gene range 2–10): AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1.
- chr7:54,542,325–55,955,239, 41 genes, copy number 6–10 (within-gene range 3–10): VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713.
- chr9:13,274,510–15,544,294, 38 genes, copy number 18–34: AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:15,588,355–15,588,615, 1 gene, copy number 19: HMGN2P16.
- chr19:37,728,586–38,899,862, 52 genes, copy number 6 (within-gene range 1–6): AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2.

Autosomal genes at a single copy (total copy number 1): 10,845. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
